Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3514, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3514-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Right hemicolectomy specimen with an ulcerated colon carcinoma conforming to the histological type of a moderately differentiated colorectal adenocarcinoma, located 1 cm aborally from Bauhin's valve and measuring 4 cm at its greatest diameter. Invasive spread of tumour into the outer layers of the muscularis propria.
Oral and aboral resection margins and large omentum tumor-free.

Twelve mesocolic and mesenteric tumor-free lymph nodes, with uncharacteristic reactive changes.

Tumor stage is therefore pT2 pN0 (1/12), L0, V0; G2,

Source: NCI Genomic Data Commons file 8ff21ff7-49c8-4478-b81d-c213b2f5f662 (TCGA-AA-3514.FB5F0B24-DA5D-4C30-B508-7D45CC48A4F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).